Somatic mutation profile of tumor specimen TCGA-FF-8041-01A (aliquot TCGA-FF-8041-01A-11D-2210-10) from TCGA case TCGA-FF-8041, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mediastinal (thymic) large B-cell lymphoma; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 28.7 years (10,466 days).
Specimen TCGA-FF-8041-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bce2a23a-09c0-4db0-934c-ba0b695605c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8041-10A (Blood Derived Normal), aliquot TCGA-FF-8041-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2107824-8d12-48f8-b806-48ae6ba1ef25

The open-access MAF lists 215 somatic variants for this specimen: 142 protein-altering or splice-affecting, 52 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 52, Intron 8, Frame Shift Del 7, Nonsense Mutation 6, 3'UTR 5, 5'UTR 4, In Frame Del 3, Splice Site 3, Splice Region 2, Frame Shift Ins 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.202); catalogued as rs749390394; called by muse, mutect2, varscan2
- AKR7L | c.603G>A p.G201= | Splice Region (SNP) | VAF 34/154 reads (22%) | catalogued as COSV101334307; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7123C>T p.R2375* | Nonsense Mutation (SNP) | VAF 60/153 reads (39%) | catalogued as COSV51845485; called by muse, mutect2, varscan2
- ANKRD53 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as rs1553424555; called by muse, mutect2, varscan2
- BICDL1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373363052; called by muse, mutect2, varscan2
- BRINP1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1292528867, COSV56312556; called by muse, mutect2, varscan2
- CACNA1F | c.5752G>A p.V1918M | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs782268897, COSV59905523; called by muse, mutect2, varscan2
- CD177 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759856388, COSV100945979; called by muse, mutect2, varscan2
- CD70 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99835597; called by muse, mutect2, varscan2
- CELA3B | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770398632, COSV100448824; called by muse, mutect2, varscan2
- CHD4 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 73/211 reads (35%) | catalogued as COSV58894277; called by muse, mutect2, varscan2
- CHTF18 | c.609C>T p.G203= | Splice Region (SNP) | VAF 19/86 reads (22%) | catalogued as rs754889987; called by muse, mutect2, varscan2
- CRISPLD1 | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV51548370; called by muse, mutect2, varscan2
- CTR9 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV63729675; called by muse, mutect2, varscan2
- CUL4A | c.1850C>T p.T617M (on ENST00000375440 / NM_001008895.4; = p.T517M on NM_003589.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746563007, COSV58375760; called by muse, mutect2, varscan2
- CYP2C19 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV64908392; called by muse, mutect2, varscan2
- DACH1 | c.683C>G p.T228R | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100499153, COSV57496016; called by muse, mutect2, varscan2
- DHRS7B | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs747710075, COSV60888075; called by muse, mutect2, varscan2
- DNAH14 | c.3434G>A p.R1145Q (on ENST00000445597; = p.R1529Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284726144, COSV60737430; called by muse, mutect2, varscan2
- EIF3D | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs1437582072; called by muse, mutect2, varscan2
- EML2 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs763267506; called by muse, mutect2, varscan2
- FAT1 | c.1078T>G p.F360V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.344); catalogued as rs975898847; called by muse, mutect2, varscan2
- FLG2 | c.4337C>T p.T1446I | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1015695920; called by muse, mutect2, varscan2
- FNIP1 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100330606; called by muse, mutect2, varscan2
- GOLGA4 | c.3872C>A p.S1291Y | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201516912, COSV62709365, COSV62712794; called by muse, mutect2, varscan2
- GRN | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs63750116, COSV99275288; ClinVar: not provided; called by muse, mutect2, varscan2
- H1-2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781062933, COSV100642241, COSV59192424; called by muse, varscan2
- H1-2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as COSV59190632; called by muse, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs777829525; called by mutect2, varscan2
- HSPA2 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV55971071; called by muse, mutect2, varscan2
- IGHV3-74 | c.227G>C p.S76T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.01); catalogued as rs1065070; called by muse, varscan2
- IGHV3-74 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs373966551; called by muse, varscan2
- IL4R | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50140034; called by muse, mutect2, varscan2
- ITPKB | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as rs761878359, COSV99684033; called by muse, mutect2, varscan2
- JAK3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV71685401; called by muse, mutect2, varscan2
- KIAA1671 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1447775392; called by muse, mutect2, varscan2
- LAMA5 | c.7474G>A p.A2492T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373181217; called by muse, mutect2, varscan2
- LAP3 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as rs1288287427; called by muse, mutect2, varscan2
- LONRF3 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV59150897; called by muse, mutect2, varscan2
- LRP1B | c.8833C>T p.L2945F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV67237161; called by muse, mutect2, varscan2
- MED26 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV54661854; called by muse, mutect2, varscan2
- MED26 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201182566; called by muse, mutect2, varscan2
- MRM3 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as rs911617060; called by muse, mutect2, varscan2
- MUSK | c.1088G>T p.S363I | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV51880043; called by muse, mutect2, varscan2
- MYCBP2 | c.10916C>T p.A3639V (on ENST00000357337; = p.A3677V on NM_015057.5) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs756209448; called by muse, mutect2, varscan2
- NBEA | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100081184; called by muse, mutect2, varscan2
- NEUROD1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs773337298, COSV54551014, COSV99716729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPN1LW | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100885046; called by muse, mutect2, varscan2
- P2RY8 | c.878A>T p.Y293F | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV67177465; called by muse, mutect2, varscan2
- PABPC1 | c.973-1G>T p.X325_splice | Splice Site (SNP) | VAF 39/117 reads (33%) | catalogued as COSV59405764; called by muse, mutect2, varscan2
- PAX8 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640013; called by muse, mutect2, varscan2
- PCDHB1 | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60632884; called by muse, mutect2, varscan2
- PDZD7 | c.1349A>C p.E450A | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100931650; called by muse, mutect2, varscan2
- PITX2 | c.766G>A p.A256T (on ENST00000354925 / NM_001204397.1; = p.A263T on NM_000325.6) | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as rs149181425; called by muse, mutect2, varscan2
- PKHD1L1 | c.9573G>T p.W3191C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217657228; called by muse, mutect2, varscan2
- PLA2G4C | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs370150895; called by muse, mutect2, varscan2
- PLET1 | c.448+1G>A p.X150_splice | Splice Site (SNP) | VAF 31/79 reads (39%) | catalogued as rs768094916, COSV100126072; called by muse, mutect2, varscan2
- PMPCA | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs367845329; called by muse, mutect2, varscan2
- POTEF | c.1202T>C p.M401T | Missense Mutation (SNP) | VAF 260/984 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100664989; called by muse, mutect2, varscan2
- PPP1R42 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs200466525, COSV100221053; called by muse, mutect2, varscan2
- PPP2R2B | c.1112G>A p.R371H (on ENST00000394409; = p.R437H on NM_181674.2) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs766221987; called by muse, mutect2, varscan2
- PRMT8 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1272004737, COSV54213052; called by muse, mutect2, varscan2
- RBM20 | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1405564573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1184536991; called by muse, mutect2, varscan2
- SERINC3 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs758967791, COSV54857452; called by muse, mutect2, varscan2
- SH3GL3 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376114446, COSV61056328; called by muse, mutect2, varscan2
- SLC25A37 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99264215; called by muse, mutect2, varscan2
- SLITRK2 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1569506573; called by muse, mutect2, varscan2
- STAT6 | c.1568A>G p.D523G | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55666466, COSV55667527; called by muse, mutect2, varscan2
- SYT10 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99951521; called by muse, mutect2, varscan2
- UBE2A | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 191/476 reads (40%) | catalogued as COSV60635930; called by muse, mutect2, varscan2
- UNC45B | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776516841, COSV52093561; called by muse, mutect2, varscan2
- USP17L2 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as rs201012791; called by muse, mutect2, varscan2
- VWDE | c.1958T>C p.L653P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV51726755; called by muse, mutect2, varscan2
- XIRP2 | c.9264G>T p.R3088S (on ENST00000628543; = p.R3263S on NM_152381.6) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1484766449; called by muse, mutect2, varscan2
- ZMIZ2 | c.450_467del p.V153_A158del | In Frame Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1208913503; called by mutect2, pindel, varscan2
- ZNF462 | c.5428G>A p.V1810I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs376844260; called by muse, mutect2, varscan2
- ABCC3 | c.3778G>T p.V1260F | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ABCC6 | c.4400_4403+11delinsAA p.X1467_splice | Splice Site (DEL) | VAF 28/167 reads (17%) | called by pindel, varscan2*
- ACTB | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AMBRA1 | c.1316G>A p.R439K (on ENST00000458649 / NM_001367468.1; = p.R349K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARMH4 | c.1709A>G p.E570G | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- B2M | c.22_37del p.A8Sfs*31 | Frame Shift Del (DEL) | VAF 42/73 reads (58%) | called by mutect2, pindel, varscan2
- BICRAL | c.1340A>T p.N447I | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CARD11 | c.1256T>G p.I419S | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CD200 | c.103T>G p.F35V (on ENST00000473539 / NM_001004196.3; = p.F10V on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDH4 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CIITA | c.3058del p.L1020Sfs*30 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- CNTRL | c.6116G>T p.G2039V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COCH | c.1324A>C p.S442R (on ENST00000216361 / NM_001347720.1; = p.S377R on NM_004086.3) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP2 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, varscan2
- ERAP1 | c.2479del p.I827* | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- EYS | c.5401G>C p.A1801P | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM107B | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GLI1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- GLIS1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- HECW2 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- HYAL3 | c.689A>C p.Q230P | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- IGFBP4 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLC2 | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 125/718 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT12 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LCMT1 | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC15 | c.1448G>C p.S483T | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.6568G>A p.V2190I | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANSC4 | c.306_313delinsT p.L103Afs*4 | Frame Shift Del (DEL) | VAF 61/182 reads (34%) | called by pindel, varscan2*
- MROH1 | c.2830G>T p.A944S | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NCDN | c.1628C>T p.T543I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NFKB2 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NKAIN2 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPAT | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 50/353 reads (14%) | called by muse, mutect2, varscan2
- NXPE2 | c.1003dup p.M335Nfs*8 | Frame Shift Ins (INS) | VAF 65/216 reads (30%) | called by mutect2, varscan2
- PBDC1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGR | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO1 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- PIGP | c.412A>T p.I138F (on ENST00000464265 / NM_153681.2; = p.I88F on NM_016430.4) | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PIGW | c.1175A>G p.D392G | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PLXNB3 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP2R1B | c.1584_1586del p.T530del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- PPP2R5B | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- QRSL1 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- REL | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 149/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RIMS2 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- RPAP2 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAP130 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCML4 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC22C | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SKP1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- SLC25A17 | c.244T>G p.Y82D | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC45A1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SYT7 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TENM4 | c.3466_3468del p.T1156del | In Frame Del (DEL) | VAF 40/230 reads (17%) | called by pindel, varscan2
- THG1L | c.408C>G p.S136R | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TLE4 | c.2090T>G p.L697R | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFAIP3 | c.971_975del p.L324Qfs*7 | Frame Shift Del (DEL) | VAF 38/64 reads (59%) | called by pindel, varscan2
- TNRC6B | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- UBQLN2 | c.1226T>C p.M409T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- UHRF1BP1 | c.743_746dup p.Q249Hfs*15 | Frame Shift Ins (INS) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- USP11 | c.164C>T p.A55V (on ENST00000218348; = p.A12V on NM_001371072.1) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZFP36L1 | c.339_352del p.S113Rfs*7 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- ZNF101 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF189 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF502 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.5634C>T p.S1878= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- ASXL3 | c.3252T>C p.S1084= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs372707880; called by mutect2, varscan2
- AURKAIP1 | c.417C>T p.N139= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV57939894; called by muse, mutect2, varscan2
- BEST3 | c.360C>T p.H120= | Silent (SNP) | VAF 55/151 reads (36%) | catalogued as rs1050889987; called by muse, mutect2, varscan2
- BLVRB | c.147C>T p.H49= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as rs747352017, COSV54568675; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMP5 | c.720C>A p.A240= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- BUB1B | c.31C>T p.L11= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs776214483; called by muse, mutect2, varscan2
- C5orf38 | c.132G>A p.A44= | Silent (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- CCDC87 | c.1296T>A p.T432= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CDC42BPG | c.4455G>A p.E1485= | Silent (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- DPYSL5 | c.384C>T p.Y128= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs147434661; called by muse, mutect2, varscan2
- DRP2 | c.1986C>T p.S662= | Silent (SNP) | VAF 64/330 reads (19%) | called by muse, mutect2, varscan2
- ELF1 | c.1539G>A p.Q513= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs1427424247; called by muse, mutect2, varscan2
- GRAMD2B | c.552C>T p.N184= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as rs375006587; called by muse, mutect2, varscan2
- IDNK | c.297T>C p.D99= | Silent (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- IGHE | c.240G>A p.K80= | Silent (SNP) | VAF 86/161 reads (53%) | called by muse, mutect2, varscan2
- IRS1 | c.1890A>T p.G630= | Silent (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- IRX4 | c.1266C>T p.G422= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1158300662; called by mutect2, varscan2
- ITPKB | c.12C>T p.Y4= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- ITPR2 | c.462A>T p.A154= | Silent (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1884C>T p.H628= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- KCNK1 | c.363C>G p.G121= | Silent (SNP) | VAF 98/214 reads (46%) | called by muse, mutect2, varscan2
- KIAA1549 | c.1893G>A p.P631= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1331337813; called by muse, mutect2, varscan2
- KIF16B | c.2334C>T p.L778= | Silent (SNP) | VAF 71/192 reads (37%) | called by muse, mutect2, varscan2
- LGI1 | c.606C>A p.G202= | Silent (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- MAGEE1 | c.315G>A p.L105= | Silent (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- MBD1 | c.1728T>C p.I576= (on ENST00000269468 / NM_001323950.1; = p.I474= on NM_002384.2) | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs759306269; called by muse, mutect2, varscan2
- MYO18B | c.723G>A p.V241= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs762093319; called by muse, mutect2, varscan2
- NCOA3 | c.1905C>T p.S635= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs748431570, COSV59070331; called by muse, mutect2, varscan2
- OR2W3 | c.582C>T p.A194= | Silent (SNP) | VAF 64/298 reads (21%) | called by muse, mutect2
- PCDHB16 | c.2094G>A p.S698= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV53359982, COSV53365989; called by muse, mutect2
- PCDHB7 | c.2013G>A p.L671= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PDGFB | c.285C>T p.A95= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs147036196; called by muse, mutect2, varscan2
- PIK3AP1 | c.2163C>T p.S721= | Silent (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- PLCB4 | c.1386C>T p.N462= | Silent (SNP) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- PMFBP1 | c.846C>T p.A282= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as rs144150480; called by muse, mutect2, varscan2
- PON3 | c.18G>A p.A6= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55700827; called by muse, mutect2, varscan2
- PPIB | c.72C>T p.F24= | Silent (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- PRKD1 | c.2592T>C p.S864= | Silent (SNP) | VAF 36/178 reads (20%) | catalogued as COSV59588656; called by muse, varscan2
- PTH2R | c.1407A>C p.T469= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- PWWP3B | c.12G>A p.E4= | Silent (SNP) | VAF 126/243 reads (52%) | called by muse, mutect2, varscan2
- SEMA5B | c.2109C>T p.C703= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs769208908, COSV52103093; called by muse, mutect2, varscan2
- SEMA6D | c.3117G>A p.R1039= (on ENST00000316364 / NM_153618.2; = p.R977= on NM_020858.2) | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- SHROOM1 | c.1554C>T p.P518= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs1297949855, COSV100167302; called by muse, mutect2, varscan2
- SOCS1 | c.528G>A p.E176= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV59659953, COSV59660643; called by muse, mutect2, varscan2
- SSX3 | c.415C>T p.L139= | Silent (SNP) | VAF 329/770 reads (43%) | called by muse, mutect2, varscan2
- SYMPK | c.372C>T p.N124= | Silent (SNP) | VAF 128/245 reads (52%) | catalogued as rs766252934; called by muse, mutect2, varscan2
- TMEM229A | c.243G>A p.P81= | Silent (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.207G>A p.E69= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV99174274, COSV99174292; called by muse, mutect2, varscan2
- WDR87 | c.7704C>T p.A2568= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as COSV58194565; called by muse, mutect2, varscan2
- ZNF14 | c.1863A>G p.G621= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- ZNF816 | c.69C>G p.R23= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- AIMP1 | c.-15C>T | 5'UTR (SNP) | VAF 62/273 reads (23%) | catalogued as rs751610778, COSV99913055; called by muse, mutect2, varscan2
- C6orf223 | n.48G>C | RNA (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+17477C>T | Intron (SNP) | VAF 21/95 reads (22%) | catalogued as rs1008659735, COSV99367578; called by muse, mutect2, varscan2
- CFL1 | c.-7C>T | 5'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100354094; called by muse, mutect2, varscan2
- DCAF12 | chr9:34127301 C>A | 5'Flank (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- FAM184A | c.3342-610G>A | Intron (SNP) | VAF 95/209 reads (45%) | catalogued as rs182566160, COSV58858741; called by muse, mutect2, varscan2
- FARP1 | c.2274+226C>T | Intron (SNP) | VAF 38/99 reads (38%) | catalogued as rs780703280; called by muse, mutect2, varscan2
- FOXL1 | c.*178C>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100206303; called by muse, mutect2, varscan2
- FZD9 | c.*110G>C | 3'UTR (SNP) | VAF 55/131 reads (42%) | catalogued as COSV100289841; called by muse, mutect2, varscan2
- HAT1 | c.-8G>A | 5'UTR (SNP) | VAF 26/54 reads (48%) | catalogued as rs755017636, COSV99907995; called by muse, mutect2, varscan2
- HBS1L | c.430+2017C>G | Intron (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.927+37C>T | Intron (SNP) | VAF 6/69 reads (9%) | catalogued as rs1214056634, COSV58488879; called by muse, mutect2
- KLRA1P | n.512T>C | RNA (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- PDP2 | c.*162A>G | 3'UTR (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100305850; called by muse, mutect2, varscan2
- RPL18 | c.3+10C>T | Intron (SNP) | VAF 71/116 reads (61%) | catalogued as rs754357500; called by muse, mutect2, varscan2
- RTL8C | c.*151G>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99924342; called by muse, mutect2, varscan2
- SSTR2 | c.*1214G>A | 3'UTR (SNP) | VAF 19/49 reads (39%) | catalogued as rs888061383, COSV59536165; called by muse, mutect2, varscan2
- TMPRSS5 | c.-44_-40dup | 5'UTR (INS) | VAF 46/156 reads (29%) | called by pindel, varscan2
- TPP2 | c.2952+1891C>T | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as rs1338435865; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331260 A>G | 5'Flank (SNP) | VAF 16/67 reads (24%) | catalogued as rs756348475; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-902A>G | Intron (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
